Somatic mutation profile of tumor specimen TCGA-BQ-7046-01A (aliquot TCGA-BQ-7046-01A-11D-1961-08) from TCGA case TCGA-BQ-7046, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.2 years (22,337 days).
Specimen TCGA-BQ-7046-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da0cdf07-e1d4-4b23-a12a-9d03a090310b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7046-11A (Solid Tissue Normal), aliquot TCGA-BQ-7046-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f307e906-72a1-400b-9416-95c7c234b023

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Frame Shift Del 6, 3'Flank 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs373621431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM11 | c.2003C>G p.P668R | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52347268, COSV52349498; called by muse, mutect2
- ADAR | c.2330A>G p.K777R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197574959, COSV52720173; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APMAP | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV54176746; called by muse, mutect2, varscan2
- CAMKK1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as rs1278741143, COSV50124774; called by muse, mutect2, varscan2
- CAND1 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.079); catalogued as COSV73338629, COSV73338658; called by muse, mutect2, varscan2
- CEACAM5 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs146319665; called by muse, mutect2, varscan2
- CHD8 | c.5447A>T p.E1816V (on ENST00000646647 / NM_001170629.2; = p.E1537V on NM_020920.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63036629, COSV63037392; called by muse, mutect2, varscan2
- DMXL1 | c.7235C>G p.P2412R | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60719778; called by muse, mutect2, varscan2
- DNAJB12 | c.617A>T p.Q206L (on ENST00000338820; = p.Q172L on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.03); catalogued as COSV58761487; called by muse, mutect2, varscan2
- DSCAM | c.3893C>T p.P1298L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68034609; called by muse, mutect2, varscan2
- HPS3 | c.1502A>G p.K501R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV56057166; called by muse, mutect2, varscan2
- KIAA0319 | c.1473G>C p.L491F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65501757; called by muse, mutect2, varscan2
- KRT40 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV66696865; called by muse, mutect2, varscan2
- LRP6 | c.1140A>C p.E380D | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV53793156; called by muse, mutect2, varscan2
- NCOA3 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV59072692; called by muse, mutect2, varscan2
- NR2F2 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV67684063; called by muse, mutect2, varscan2
- NRXN2 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1428772338, COSV55458010; called by muse, mutect2, varscan2
- PARD3 | c.2066A>G p.E689G | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV60759949; called by muse, mutect2, varscan2
- RBM47 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55942295, COSV55943860; called by muse, mutect2, varscan2
- SNAP29 | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.464); catalogued as COSV53142814, COSV53144058; called by muse, mutect2, varscan2
- STPG2 | c.1228T>A p.L410I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.34); catalogued as COSV54817334; called by muse, mutect2, varscan2
- SVIL | c.3361C>G p.P1121A (on ENST00000355867 / NM_021738.3; = p.P695A on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs775889275, COSV63447553; called by muse, varscan2
- TMEM26 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV67493142; called by muse, mutect2, varscan2
- BACH1 | c.721del p.T241Lfs*35 | Frame Shift Del (DEL) | VAF 33/116 reads (28%) | called by mutect2, pindel, varscan2
- CNTLN | c.3342del p.N1114Kfs*2 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- FGL2 | c.385dup p.R129Kfs*3 | Frame Shift Ins (INS) | VAF 26/145 reads (18%) | called by mutect2, pindel, varscan2
- KAT6A | c.1042del p.V348Yfs*37 | Frame Shift Del (DEL) | VAF 90/362 reads (25%) | called by mutect2, pindel, varscan2
- RSPRY1 | c.1232del p.N411Mfs*18 | Frame Shift Del (DEL) | VAF 42/96 reads (44%) | called by mutect2, pindel, varscan2
- SPINDOC | c.983_984del p.V328Afs*28 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- TMEM237 | c.839del p.L280Wfs*3 (on ENST00000409883 / NM_001044385.3; = p.L272Wfs*3 on NM_152388.4) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1S | c.2838C>A p.G946= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs759934490, COSV62943091; called by muse, mutect2, varscan2
- CDK11A | c.1188C>A p.P396= (on ENST00000378633 / NM_001313896.2; = p.P393= on NM_024011.4) | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV62264768, COSV62266746; called by mutect2, varscan2
- CGN | c.3552C>T p.Y1184= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs747235870, COSV54973091; called by muse, mutect2, varscan2
- DNAH11 | c.6093A>G p.L2031= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV60977373; called by muse, mutect2, varscan2
- FZR1 | c.120G>A p.S40= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs201664307; called by muse, mutect2, varscan2
- GPRC5C | c.273T>A p.S91= (on ENST00000652232; = p.S46= on NM_018653.4) | Silent (SNP) | VAF 86/156 reads (55%) | catalogued as COSV61238582; called by muse, mutect2, varscan2
- MYBBP1A | c.1578G>A p.T526= | Silent (SNP) | VAF 98/179 reads (55%) | catalogued as rs749276581, COSV54602574; called by muse, varscan2
- ROBO4 | c.858C>T p.T286= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV60627585; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100323 del G | 3'Flank (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
